Somatic mutation profile of tumor specimen ALCH-B40Y-TTP1-A (aliquot ALCH-B40Y-TTP1-A-6-0-D-A80D-36) from ALCHEMIST case ALCH-B40Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.3 years (26,415 days).
Specimen ALCH-B40Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4dd9802-f19c-4280-8a7d-a0f6f805084d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B40Y-NB1-A (Blood Derived Normal), aliquot ALCH-B40Y-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b8accfd-79b9-4712-a342-611844698603

The open-access MAF lists 32 somatic variants for this specimen: 17 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 12, Nonsense Mutation 3, Intron 1, 3'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs371102650; called by muse, mutect2, varscan2
- CASP8AP2 | c.1454A>T p.H485L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV99387663; called by muse, mutect2, varscan2
- GLUD2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 93/1573 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs200880803, COSV60151559, COSV60152177; called by muse, mutect2
- GPR83 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 57/494 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV99703957; called by muse, mutect2, varscan2
- NHLRC3 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 117/1312 reads (9%) | catalogued as COSV100612750; called by muse, mutect2
- OCRL | c.890G>A p.W297* | Nonsense Mutation (SNP) | VAF 46/371 reads (12%) | catalogued as CM011445; called by muse, mutect2, varscan2
- PCDH11X | c.142A>T p.N48Y | Missense Mutation (SNP) | VAF 88/984 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53439114; called by muse, mutect2
- SLC25A14 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as COSV54417458; called by muse, mutect2, varscan2
- STAG1 | c.3400C>T p.Q1134* | Nonsense Mutation (SNP) | VAF 28/210 reads (13%) | catalogued as COSV99365087; called by muse, mutect2, varscan2
- BPIFB3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- FBXL7 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 35/942 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- GXYLT1 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.17); called by muse, mutect2
- NEIL1 | c.119T>C p.F40S | Missense Mutation (SNP) | VAF 158/1712 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR5B3 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.071); called by muse, mutect2
- ST18 | c.866T>C p.M289T | Missense Mutation (SNP) | VAF 80/743 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- TRIM59 | c.1170del p.Y391Ifs*3 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel
- TRIM71 | c.716A>C p.E239A | Missense Mutation (SNP) | VAF 107/963 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ACSM2B | c.933C>T p.A311= | Silent (SNP) | VAF 48/451 reads (11%) | called by muse, mutect2, varscan2
- AFF3 | c.2142C>T p.N714= | Silent (SNP) | VAF 19/220 reads (9%) | catalogued as COSV57841742; called by muse, mutect2
- BCOR | c.4683C>T p.Y1561= (on ENST00000378444 / NM_001123385.2; = p.Y1527= on NM_017745.6) | Silent (SNP) | VAF 72/868 reads (8%) | called by muse, mutect2
- CCDC86 | c.99G>A p.V33= | Silent (SNP) | VAF 52/965 reads (5%) | called by muse, mutect2
- DOCK7 | c.1005T>C p.Y335= | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- GDAP1 | c.498C>T p.N166= | Silent (SNP) | VAF 72/836 reads (9%) | called by muse, mutect2
- JPH2 | c.1803C>T p.T601= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs1060503799, COSV65906226; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNC1 | c.1230G>A p.T410= | Silent (SNP) | VAF 54/426 reads (13%) | catalogued as rs1295549018, COSV56395300; called by muse, mutect2, varscan2
- KDM5C | c.3435T>C p.S1145= | Silent (SNP) | VAF 148/1614 reads (9%) | called by muse, mutect2
- MUCL3 | c.357C>G p.P119= | Silent (SNP) | VAF 42/656 reads (6%) | called by muse, mutect2
- PLEKHG2 | c.2088A>G p.Q696= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as rs762784102; called by muse, mutect2, varscan2
- RADIL | c.3150G>A p.G1050= | Silent (SNP) | VAF 60/768 reads (8%) | called by muse, mutect2
- FAM183BP | n.1244A>G | RNA (SNP) | VAF 89/774 reads (11%) | called by muse, mutect2, varscan2
- SPTA1 | c.4980+18C>T | Intron (SNP) | VAF 47/526 reads (9%) | catalogued as rs779255170, COSV63751215; called by muse, mutect2
- TMCO1 | c.*2125A>G | 3'UTR (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2
